Gene-level copy-number profile of tumor specimen TCGA-Q1-A5R2-01A from TCGA case TCGA-Q1-A5R2, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Cervix uteri; Tumor grade: G3; Age at diagnosis: 64.4 years (23,523 days).
Specimen TCGA-Q1-A5R2-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-CESC.2fad7360-d74b-426a-8f35-ceb215226c38.absolute_liftover.gene_level_copy_number.v36.tsv, workflow ABSOLUTE segment calls lifted over to GRCh38 (Affymetrix SNP 6.0); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 3,784 have no estimate.
https://portal.gdc.cancer.gov/files/dee110d4-2767-4aa1-bcfc-6ebd81396bfa

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 3; copy number 1: 890; copy number 2: 15,328; copy number 3: 29,510; copy number 4: 8,667; copy number 5: 481; copy number 6: 1,456; copy number 7: 504.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-Q1-A5R2-01A-11D-A28A-01): tumor purity 0.57, ploidy 2.96, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 3 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:6,688,433–6,753,862, 3 genes (within-gene range 0–3): ZNF12, PMS2CL, SPDYE20P.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 504 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:15,326,680–15,343,876, 2 genes, copy number 7: FHAD1-AS1, AL031283.2.
- chr3:130,212,823–132,285,410, 31 genes, copy number 7 (within-gene range 2–7): COL6A4P2, AC093004.1, COL6A5, COL6A6, PIK3R4, RN7SKP212, AC097105.1, GSTO3P, ATP2C1, AC055733.4, AC055733.2, Y_RNA, AC055733.1, AC055733.3, ASTE1, NEK11, AC116424.1, RNU6-726P, AC010210.1, NUDT16P1, NUDT16, AC107027.3, MRPL3, SNORA58, AC107027.1, BCL2L12P1, CPNE4, AC107027.2, MIR5704, PSMC2P1, RPL7P16.
- chr3:136,336,236–137,011,085, 15 genes, copy number 7: STAG1, RNU6-1284P, HMGN1P10, RNU6-789P, AC117382.1, AC117382.2, AC096992.3, AC096992.1, SLC35G2, NCK1-DT, AC096992.2, NCK1, RAD51AP1P1, IL20RB, IL20RB-AS1.
- chr3:169,003,022–192,767,764, 411 genes, copy number 7 (within-gene range 2–7) (broad region; genes not listed).
- chr11:86,955,616–89,065,945, 34 genes, copy number 7 (within-gene range 2–7): FZD4-DT, HNRNPCP8, TMEM135, XIAPP2, AP002967.1, AP001102.1, AP000811.1, PSMA2P1, AP003497.1, AP003497.2, AP001784.1, RNU6-1135P, U6, LINC02711, AP000756.1, MTCYBP41, AP000676.2, AP000676.3, AP000676.5, AP000676.4, AP000676.1, AP005436.3, AP005436.1, AP005436.2, Y_RNA, RAB38, AP001642.1, MIR3166, CTSC, GAPDHP70, AP003120.1, GRM5-AS1, GRM5, RNU6-16P.
- chr14:47,760,995–48,491,767, 11 genes, copy number 7: MIR548Y, LINC00648, AL121576.1, AL359212.1, AL512358.1, AL512358.2, AL358335.3, RNU6-297P, AL358335.2, AL358335.1, RPL18P1.

Autosomal genes at a single copy (total copy number 1): 890. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
